Somatic mutation profile of tumor specimen TCGA-G2-A3VY-01A (aliquot TCGA-G2-A3VY-01A-11D-A22Z-08) from TCGA case TCGA-G2-A3VY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.0 years (24,112 days).
Specimen TCGA-G2-A3VY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f028f58b-7607-4680-ba84-758f33809185.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A3VY-10A (Blood Derived Normal), aliquot TCGA-G2-A3VY-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73a4fa04-cdf2-44fb-805a-ed37f9d71794

The open-access MAF lists 825 somatic variants for this specimen: 625 protein-altering or splice-affecting, 184 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 533, Silent 184, Nonsense Mutation 53, Splice Site 15, Frame Shift Del 12, Intron 6, In Frame Del 5, 5'UTR 3, Nonstop Mutation 3, RNA 3, 3'Flank 2, Splice Region 2.

Variants (750 of 825; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FH | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691244, COSV100845002, COSV63818992; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 32/35 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.3365G>A p.R1122H | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs777730176, COSV59392370; called by muse, mutect2, varscan2
- AAR2 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV57924933; called by muse, mutect2, varscan2
- AASS | c.69A>T p.K23N | Missense Mutation (SNP) | VAF 116/192 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV62791726; called by muse, mutect2, varscan2
- ABCA13 | c.12160T>C p.C4054R | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71294095; called by muse, mutect2, varscan2
- ABCB4 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as CM154305, COSV55941577; called by muse, mutect2, varscan2
- ABCB8 | c.1385G>T p.C462F (on ENST00000297504 / NM_001282291.2; = p.C445F on NM_007188.5) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.122); catalogued as COSV52510206; called by muse, varscan2
- ABCD3 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59867699; called by muse, mutect2, varscan2
- ABHD15 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV56196681; called by muse, mutect2, varscan2
- AC006059.2 | c.654G>C p.Q218H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV59609490; called by muse, mutect2, varscan2
- AC090517.4 | c.485C>G p.S162* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV50995863; called by muse, mutect2
- ACAN | c.2774G>A p.R925K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV61369203; called by muse, mutect2, varscan2
- ACOT13 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57764538, COSV57765726; called by muse, mutect2, varscan2
- ACTN2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as COSV63978195; called by muse, mutect2, varscan2
- ADA | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs1427855345, COSV65740807; called by muse, mutect2, varscan2
- ADAT1 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57188431; called by muse, mutect2, varscan2
- AHNAK | c.12449C>T p.S4150F | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57216197; called by muse, mutect2, varscan2
- AHNAK2 | c.11427G>C p.K3809N | Missense Mutation (SNP) | VAF 101/323 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV60929880, COSV60930207; called by muse, mutect2, varscan2
- ALMS1 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 147/370 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV52521755; called by muse, mutect2, varscan2
- ALMS1 | c.2635C>T p.H879Y | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV52521766; called by muse, mutect2, varscan2
- ALMS1 | c.4314C>G p.F1438L | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as COSV52521790; called by muse, mutect2, varscan2
- ALMS1 | c.5065C>G p.L1689V | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV52521800; called by muse, mutect2, varscan2
- ALMS1 | c.5206C>G p.L1736V | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV52521808; called by muse, mutect2, varscan2
- ANKRD11 | c.4896G>C p.K1632N | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV56371652; called by muse, mutect2
- ANLN | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.159); catalogued as rs549587288, COSV56079427; called by muse, mutect2, varscan2
- APLP2 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.816); catalogued as rs770621673, COSV53844404; called by muse, mutect2, varscan2
- ARAP1 | c.2225C>T p.P742L (on ENST00000393609 / NM_001040118.2; = p.P497L on NM_015242.4) | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1278442255, COSV61994967; called by muse, mutect2, varscan2
- ARHGAP35 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV68335546; called by muse, mutect2, varscan2
- ARHGAP35 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as COSV101351607, COSV68335558; called by muse, mutect2, varscan2
- ARHGAP35 | c.2540G>C p.R847T | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68335569; called by muse, mutect2, varscan2
- ARHGAP6 | c.1479C>T p.L493= | Splice Region (SNP) | VAF 59/63 reads (94%) | catalogued as COSV100272524, COSV57303232; called by muse, mutect2, varscan2
- ARHGEF10L | c.3280C>T p.R1094W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs765044758, COSV51427252; called by muse, mutect2, varscan2
- ARHGEF12 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63107309; called by muse, mutect2, varscan2
- ART1 | c.200C>A p.T67K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV51707140; called by muse, mutect2, varscan2
- ARTN | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as rs373730001; called by muse, mutect2, varscan2
- ASAP1 | c.1218-1G>A p.X406_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | catalogued as COSV63054354; called by muse, mutect2, varscan2
- ASH1L | c.4357C>G p.L1453V | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64213640; called by muse, mutect2, varscan2
- ATF7 | c.1034G>A p.R345Q (on ENST00000548446 / NM_001366555.2; = p.R334Q on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1333584812, COSV60646334; called by muse, mutect2, varscan2
- ATG2A | c.3457C>A p.L1153M | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.896); catalogued as COSV65968865; called by muse, mutect2, varscan2
- ATMIN | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 98/327 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs199871299, COSV55147586; called by muse, mutect2, varscan2
- ATMIN | c.2200G>T p.D734Y | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100214698, COSV55147595; called by muse, varscan2
- ATP1A2 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63405830; called by muse, mutect2, varscan2
- ATP6V1A | c.193C>G p.Q65E | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV56364640; called by muse, mutect2, varscan2
- ATP6V1B1 | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV52271973; called by muse, mutect2
- BBS10 | c.852G>C p.Q284H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV53889088; called by muse, mutect2, varscan2
- BCAN | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as rs773025510; called by muse, mutect2, varscan2
- BOD1L1 | c.3768G>C p.L1256F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV50063027, COSV99239361; called by muse, mutect2
- BORCS5 | c.210G>C p.L70F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV53801187, COSV53802847; called by muse, mutect2, varscan2
- BTAF1 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV56437071, COSV56439368; called by muse, mutect2, varscan2
- BTBD9 | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58435746; called by muse, mutect2, varscan2
- BTG2 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51857200, COSV51858153; called by muse, mutect2, varscan2
- C2orf16 | c.4915C>T p.R1639C | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1426537450, COSV62675332; called by muse, mutect2, varscan2
- C8orf76 | c.610T>G p.F204V | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV52691967; called by muse, mutect2, varscan2
- C9orf152 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as rs752224113, COSV68762822, COSV68763148; called by muse, mutect2, varscan2
- CACNB4 | c.553G>C p.G185R | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV52403221; called by muse, mutect2, varscan2
- CACNG7 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55814098, COSV55817251; called by muse, mutect2
- CALU | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs763463415, COSV50823420; called by muse, mutect2, varscan2
- CAMSAP2 | c.30G>C p.M10I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52677198; called by muse, mutect2
- CAPN9 | c.2064G>T p.M688I | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV55239557; called by muse, mutect2, varscan2
- CARMIL1 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs763392762, COSV61520503; called by muse, mutect2, varscan2
- CCDC157 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs5753102, COSV57842260; called by muse, mutect2, varscan2
- CCDC22 | c.1691A>T p.H564L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66052024; called by muse, mutect2, varscan2
- CCDC33 | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV58357934; called by muse, mutect2, varscan2
- CCDC66 | c.2812G>A p.E938K (on ENST00000394672 / NM_001353147.1; = p.E904K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV58309313; called by muse, mutect2, varscan2
- CCDC73 | c.2931G>C p.L977F | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV58804676; called by muse, mutect2, varscan2
- CCDC9B | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs746433187, COSV66876258; called by muse, mutect2, varscan2
- CCNB3 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as COSV52073313; called by muse, mutect2, varscan2
- CCNK | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66275820; called by muse, mutect2, varscan2
- CCNL2 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs776619502, COSV68767138; called by muse, mutect2, varscan2
- CCT2 | c.1059G>T p.M353I | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV54741567; called by muse, mutect2, varscan2
- CDAN1 | c.3223G>T p.E1075* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV62331910; called by muse, mutect2, varscan2
- CDH6 | c.1581G>C p.L527F | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV54078131, COSV54078149; called by muse, mutect2, varscan2
- CDH7 | c.1373-1G>C p.X458_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV59894421; called by muse, mutect2, varscan2
- CDKN2A | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58715972; called by muse, mutect2, varscan2
- CDT1 | c.300A>C p.K100N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV56350096; called by muse, mutect2, varscan2
- CELF2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 44/282 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV64934417; called by muse, mutect2, varscan2
- CELSR3 | c.8825-1G>A p.X2942_splice | Splice Site (SNP) | VAF 27/48 reads (56%) | catalogued as COSV51148710; called by muse, mutect2
- CELSR3 | c.933C>G p.N311K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51148790; called by muse, mutect2, varscan2
- CEP104 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 87/130 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65512872, COSV65512990; called by muse, mutect2, varscan2
- CEP250 | c.3759G>T p.W1253C | Missense Mutation (SNP) | VAF 87/113 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV61174294; called by muse, mutect2, varscan2
- CEP250 | c.6403G>C p.E2135Q | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); catalogued as COSV61174301; called by muse, mutect2
- CFAP251 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV56615827; called by muse, mutect2, varscan2
- CFAP45 | c.534G>C p.Q178H | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV63651079; called by muse, mutect2, varscan2
- CFTR | c.1931T>C p.L644P | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50098190; called by muse, mutect2, varscan2
- CGNL1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as rs761709518, COSV55575015; called by muse, mutect2, varscan2
- CHD2 | c.4235A>C p.E1412A | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV101245421; called by muse, mutect2
- CHD7 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV71114483; called by muse, mutect2, varscan2
- CHRD | c.2828G>A p.R943K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as COSV52606035; called by muse, mutect2, varscan2
- CLASP2 | c.2530G>C p.D844H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56277053, COSV56282419, COSV56293642; called by muse, mutect2, varscan2
- CLTC | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52253079; called by muse, mutect2, varscan2
- CLUL1 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as COSV58111927; called by muse, mutect2, varscan2
- CLYBL | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59229114; called by muse, mutect2, varscan2
- CNNM4 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.149); catalogued as COSV65662111; called by muse, mutect2, varscan2
- CNOT1 | c.6136A>G p.I2046V | Missense Mutation (SNP) | VAF 105/138 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV55322237; called by muse, mutect2, varscan2
- CNP | c.740del p.P247Qfs*28 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs1352175001; called by mutect2, pindel, varscan2
- CNTNAP5 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV70470072; called by muse, mutect2, varscan2
- COG8 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV54743554; called by muse, mutect2, varscan2
- COL11A1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.142); catalogued as COSV62186300; called by muse, mutect2, varscan2
- COPS2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV54647536; called by muse, mutect2, varscan2
- COPS4 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52313498; called by muse, mutect2, varscan2
- COPZ2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV50058421, COSV99133599; called by muse, mutect2, varscan2
- CORO1B | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV58171470; called by muse, mutect2, varscan2
- COX7A1 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53085361; called by muse, mutect2, varscan2
- CRMP1 | c.612G>C p.L204F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV61482944; called by muse, mutect2, varscan2
- CTNNBL1 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.408); catalogued as COSV63747266; called by muse, mutect2, varscan2
- CTNND2 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58888796, COSV58926836; called by muse, mutect2, varscan2
- CUL1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV57392513; called by muse, mutect2, varscan2
- CX3CR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64193623, COSV64195299; called by muse, mutect2, varscan2
- CYP2A6 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs560382680, COSV56537145; called by muse, mutect2, varscan2
- DAGLA | c.284A>C p.Q95P | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.969); catalogued as COSV57199617; called by muse, mutect2, varscan2
- DBF4B | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs367600377; called by muse, mutect2, varscan2
- DCLRE1C | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs753690114, COSV63185391; called by muse, mutect2, varscan2
- DDX3X | c.759G>A p.M253I (on ENST00000399959; = p.M254I on NM_001356.5) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV67864516; called by muse, mutect2, varscan2
- DENND6A | c.975C>G p.F325L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV60770143; called by muse, mutect2, varscan2
- DGKI | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs915918634, COSV55942334, COSV55974972; called by muse, mutect2
- DHX16 | c.2161C>G p.Q721E | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53315993; called by muse, mutect2, varscan2
- DICER1 | c.3442C>G p.Q1148E | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.098); catalogued as COSV58628021; called by muse, mutect2, varscan2
- DKC1 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV65778198; called by muse, mutect2, varscan2
- DMXL2 | c.5382del p.P1795Lfs*10 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as COSV51855968; called by mutect2, pindel, varscan2
- DNAH3 | c.6943C>G p.L2315V | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54550729; called by muse, mutect2, varscan2
- DNAJC14 | c.1990T>C p.F664L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV54479330; called by muse, mutect2, varscan2
- DNAJC5B | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV52538548, COSV52539918; called by muse, mutect2, varscan2
- DNM2 | c.1742C>T p.S581F (on ENST00000355667 / NM_001005360.3; = p.S577F on NM_004945.3) | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV58971703; called by muse, mutect2, varscan2
- DOT1L | c.2529G>C p.E843D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV67113362; called by muse, mutect2, varscan2
- DPY19L2 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV100116999, COSV60545905; called by muse, mutect2, varscan2
- DSCAML1 | c.3586G>A p.D1196N (on ENST00000321322; = p.D1136N on NM_020693.4) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58402467; called by muse, mutect2, varscan2
- EBNA1BP2 | c.858G>C p.K286N | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.193); catalogued as COSV52541559; called by muse, mutect2, varscan2
- EDEM1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as COSV56584163; called by muse, mutect2, varscan2
- EDEM3 | c.1179C>G p.F393L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV58927883; called by muse, mutect2, varscan2
- EFCAB6 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs780201437, COSV53072399; called by muse, mutect2, varscan2
- EGFLAM | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV59314932, COSV59316984; called by muse, mutect2, varscan2
- EGR1 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT tolerated, low confidence (0.75); PolyPhen possibly damaging (0.521); catalogued as COSV53521521; called by muse, mutect2, varscan2
- EHMT1 | c.1534G>C p.D512H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58381804; called by muse, mutect2, varscan2
- EIF4A3 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV53921612, COSV99484165; called by muse, mutect2, varscan2
- ELMO3 | c.1552G>A p.D518N (on ENST00000652269; = p.D465N on NM_024712.5) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs201129653; called by muse, mutect2, varscan2
- ELP6 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV56133179; called by muse, mutect2, varscan2
- EPC2 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs747278661, COSV51549373; called by muse, mutect2, varscan2
- EPN2 | c.1477C>G p.Q493E | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV59063420; called by muse, mutect2, varscan2
- EPN3 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52143233; called by muse, mutect2, varscan2
- EPPK1 | c.4879G>A p.E1627K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV73262365; called by muse, mutect2, varscan2
- ERAP2 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV65941364; called by muse, mutect2, varscan2
- ERBB4 | c.3847G>C p.E1283Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100728029, COSV61513416, COSV61521979; called by muse, mutect2, varscan2
- ERCC1 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as COSV50005391, COSV99185235; called by muse, mutect2, varscan2
- EVA1C | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55826677, COSV55826691; called by muse, mutect2, varscan2
- EXPH5 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV56208107; called by muse, mutect2, varscan2
- F13B | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66375654; called by muse, mutect2, varscan2
- FAF1 | c.1576-1G>C p.X526_splice | Splice Site (SNP) | VAF 35/113 reads (31%) | catalogued as COSV65643853; called by muse, mutect2, varscan2
- FAM13A | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs768654755, COSV52012981; called by muse, mutect2
- FAM162A | c.335_350del p.V112Afs*16 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as COSV51659781; called by mutect2, pindel
- FAM177B | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1289032831, COSV62601830; called by muse, mutect2, varscan2
- FAM47C | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.909); catalogued as COSV99080711; called by muse, mutect2
- FAM83H | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66354663; called by muse, mutect2, varscan2
- FANCA | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV66883833; called by muse, mutect2, varscan2
- FANCM | c.5911G>A p.E1971K | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV57506482; called by muse, mutect2, varscan2
- FBN1 | c.8592G>C p.M2864I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV57322315, COSV57330121; called by muse, mutect2, varscan2
- FBXO31 | c.1504G>C p.E502Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61151284; called by muse, mutect2, varscan2
- FCN1 | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV65662879; called by muse, mutect2, varscan2
- FDPS | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 76/167 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV63115409; called by muse, mutect2, varscan2
- FHOD1 | c.3311C>T p.S1104L | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV50769351; called by muse, mutect2
- FLG | c.7424G>C p.G2475A | Missense Mutation (SNP) | VAF 146/506 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs754539573, COSV64247311; called by muse, mutect2
- FOXG1 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57399493; called by muse, mutect2, varscan2
- FOXN3 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV54316465; called by muse, mutect2, varscan2
- FOXP2 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63490476, COSV63493819; called by muse, mutect2, varscan2
- FRG2 | c.294A>T p.R98S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1266915753, COSV66460614; called by muse, mutect2, varscan2
- FRMD4A | c.2637C>G p.F879L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs754697615, COSV62269170; called by muse, mutect2, varscan2
- FYB2 | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100599363, COSV58589190; called by muse, mutect2, varscan2
- FZD6 | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV62472173, COSV62472663; called by muse, mutect2, varscan2
- GAB4 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as rs1480666674, COSV68753582, COSV68755425; called by muse, mutect2, varscan2
- GCN1 | c.6088G>A p.E2030K | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs779688682, COSV56114652; called by muse, varscan2
- GEMIN5 | c.4350G>C p.E1450D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV53564750; called by muse, mutect2, varscan2
- GLB1 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56567929; called by muse, mutect2, varscan2
- GLDN | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV59092444; called by muse, mutect2, varscan2
- GLRX | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV52987209; called by muse, mutect2, varscan2
- GPAA1 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100284112; called by muse, mutect2, varscan2
- GPAA1 | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.405); catalogued as COSV61906474; called by muse, mutect2
- GPD2 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs770612633, COSV60096954; called by muse, mutect2, varscan2
- GPR119 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52275126, COSV52276582; called by muse, mutect2, varscan2
- GPR142 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1479249272, COSV59520450; called by muse, mutect2, varscan2
- GRIA4 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56919037; called by muse, mutect2, varscan2
- GRM1 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 47/136 reads (35%) | catalogued as COSV51235719; called by muse, mutect2, varscan2
- GRM5 | c.3596C>T p.T1199I (on ENST00000305447 / NM_001143831.2; = p.T1167I on NM_000842.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV59628982; called by muse, mutect2, varscan2
- GSTA2 | c.585G>C p.K195N | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV72415350, COSV72415549; called by muse, mutect2, varscan2
- GTF3C2 | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765758731, COSV53128737, COSV53128960; called by muse, mutect2, varscan2
- GTPBP3 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61414941; called by muse, mutect2, varscan2
- H1-8 | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV60719292; called by muse, mutect2, varscan2
- H3-3B | c.149G>C p.R50P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54665901, COSV54665976; called by muse, mutect2, varscan2
- H4C12 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100694731, COSV100694760, COSV100694763; called by muse, mutect2, varscan2
- HBQ1 | c.206T>A p.L69H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV99555287; called by muse, mutect2
- HCN1 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV57536576; called by muse, mutect2, varscan2
- HECTD1 | c.4285C>G p.L1429V | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.899); catalogued as rs769971819, COSV67949086; called by muse, mutect2, varscan2
- HEG1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV60765516; called by muse, mutect2, varscan2
- HELLS | c.309A>T p.K103N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV53301213; called by muse, mutect2, varscan2
- HEPACAM2 | c.376A>T p.I126F (on ENST00000394468 / NM_001039372.4; = p.I114F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV59063288; called by muse, mutect2, varscan2
- HERC2 | c.12412G>C p.E4138Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV55350000; called by muse, mutect2, varscan2
- HERC6 | c.3001G>C p.E1001Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV52034359; called by muse, mutect2, varscan2
- HJURP | c.2104G>C p.D702H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64979578; called by muse, mutect2, varscan2
- HLA-C | c.1048+2T>G p.X350_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV66118863; called by muse, mutect2, varscan2
- HMCN1 | c.11245G>T p.D3749Y | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54940432; called by muse, mutect2, varscan2
- HORMAD1 | c.167G>C p.R56T | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59273167; called by muse, mutect2, varscan2
- HOXA10 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52231131; called by muse, mutect2, varscan2
- HSPA14 | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as rs1305107822, COSV65685213; called by muse, mutect2, varscan2
- HYOU1 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68217348; called by muse, mutect2, varscan2
- IARS2 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56963962; called by muse, mutect2, varscan2
- IKZF3 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.717); catalogued as COSV53107045; called by muse, mutect2, varscan2
- IL17B | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51005408; called by muse, mutect2, varscan2
- IL21R | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as COSV61972538; called by mutect2, varscan2
- ILF2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV62628224; called by muse, mutect2
- IMPACT | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV52423418; called by muse, mutect2, varscan2
- INPP5J | c.1359C>A p.S453R (on ENST00000331075 / NM_001284285.2; = p.S85R on NM_001002837.2) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV58515308, COSV58515522; called by muse, mutect2, varscan2
- IPO13 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1190158235, COSV64895026; called by muse, mutect2, varscan2
- IRAG2 | c.4227G>C p.L1409F (on ENST00000636465; = p.L454F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as COSV57236683; called by muse, mutect2, varscan2
- IRAK4 | c.1254G>C p.M418I | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV71210975; called by muse, mutect2, varscan2
- ISM2 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53636974; called by muse, mutect2, varscan2
- ITIH2 | c.2482C>G p.L828V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64435196; called by muse, mutect2, varscan2
- ITK | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1230916806, COSV68435488; called by muse, mutect2, varscan2
- ITPR1 | c.7040C>T p.S2347L (on ENST00000354582; = p.S2292L on NM_002222.7) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.996); catalogued as COSV57003372; called by muse, mutect2, varscan2
- JAK1 | c.1649-1G>A p.X550_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV61095813; called by muse, mutect2
- JAML | c.820C>A p.Q274K (on ENST00000356289 / NM_001098526.2; = p.Q264K on NM_153206.3) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as COSV52629533; called by muse, mutect2, varscan2
- KANSL1 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.455); catalogued as COSV52273994; called by muse, mutect2, varscan2
- KCNK7 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV58419213; called by muse, mutect2, varscan2
- KCNS1 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60261092; called by muse, mutect2
- KCNU1 | c.1533G>C p.Q511H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV67760174; called by muse, mutect2
- KCTD18 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63344168, COSV63345145; called by muse, mutect2, varscan2
- KDM3A | c.3670C>G p.Q1224E | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as COSV57223540, COSV57225578; called by muse, mutect2, varscan2
- KDM5A | c.1583C>G p.S528C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV66996315; called by muse, mutect2, varscan2
- KIAA0513 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs373294941; called by muse, mutect2, varscan2
- KIAA1109 | c.13939G>C p.E4647Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.963); catalogued as COSV52691705; called by muse, mutect2, varscan2
- KIAA1217 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64613104; called by muse, mutect2, varscan2
- KIAA1549 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54323608, COSV54325092; called by muse, mutect2, varscan2
- KIDINS220 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as COSV56753325; called by muse, mutect2
- KLK6 | c.265G>C p.V89L | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV59566667; called by muse, mutect2, varscan2
- KMO | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.088); catalogued as COSV63807592, COSV63810623; called by muse, mutect2, varscan2
- KMT2A | c.5119G>A p.D1707N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63292416; called by muse, mutect2, varscan2
- KMT2C | c.1160A>T p.E387V | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV51501054; called by muse, mutect2
- KMT2D | c.13936G>A p.E4646K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV56471509, COSV56485227; called by muse, mutect2, varscan2
- KMT2E | c.3263C>T p.T1088I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57579597; called by muse, mutect2
- KPNA1 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769071901, COSV60271654; called by muse, mutect2, varscan2
- KRT4 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs1405060384, COSV53408725, COSV99542972; called by muse, mutect2, varscan2
- KRT84 | c.792G>C p.E264D | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57773672; called by muse, mutect2, varscan2
- L3HYPDH | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54201438; called by muse, mutect2, varscan2
- LACTB2 | c.753G>C p.E251D | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV52569564; called by muse, mutect2, varscan2
- LAMB1 | c.5234G>C p.R1745T | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV52739701; called by muse, varscan2
- LAMB1 | c.5008G>C p.E1670Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV55970040; called by muse, mutect2, varscan2
- LEO1 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55177462; called by muse, mutect2, varscan2
- LIG1 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV54395970; called by muse, mutect2, varscan2
- LIG1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV54395989; called by muse, mutect2, varscan2
- LIMA1 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV57968519; called by muse, mutect2, varscan2
- LMO4 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs139269304; called by muse, mutect2, varscan2
- LOX | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV50241067; called by muse, mutect2, varscan2
- LOXL3 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.782); catalogued as COSV51213851; called by muse, mutect2, varscan2
- LRPPRC | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1404610329, COSV53237094; called by muse, mutect2, varscan2
- LRRN1 | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV60016219; called by muse, mutect2, varscan2
- LSM14B | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1407388535, COSV53383563; called by muse, mutect2, varscan2
- LUZP2 | c.549A>T p.Q183H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.576); catalogued as COSV61218507; called by muse, mutect2, varscan2
- LY9 | c.1897C>G p.Q633E | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV54437787; called by muse, mutect2, varscan2
- LYST | c.9191C>A p.S3064* | Nonsense Mutation (SNP) | VAF 14/194 reads (7%) | catalogued as COSV101089719, COSV67707505; called by muse, mutect2
- LYST | c.9190T>A p.S3064T | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV67713863; called by muse, mutect2
- M1AP | c.1282-1G>C p.X428_splice | Splice Site (SNP) | VAF 9/64 reads (14%) | catalogued as rs77403431, COSV51848173; called by muse, mutect2, varscan2
- MAGEE1 | c.1468C>A p.P490T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63912024; called by muse, mutect2, varscan2
- MAP11 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57588287; called by mutect2, varscan2
- MAP4K1 | c.663C>G p.L221= | Splice Region (SNP) | VAF 31/57 reads (54%) | catalogued as rs752231895, COSV67713127, COSV67713634; called by muse, mutect2, varscan2
- MAPK9 | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as COSV58126074; called by muse, mutect2, varscan2
- MATN4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | PolyPhen benign (0.233); catalogued as rs758330632; called by muse, mutect2, varscan2
- MBNL2 | c.1040C>T p.S347F (on ENST00000376673 / NM_001382666.1; = p.S335F on NM_207304.3 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as COSV59125562; called by muse, mutect2, varscan2
- MCF2L2 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV61061298; called by muse, mutect2, varscan2
- MCM6 | c.2171C>G p.S724C | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV51469316; called by muse, mutect2, varscan2
- MCRIP2 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs769497190, COSV53475159; called by muse, mutect2, varscan2
- MEGF8 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52092376, COSV52101241; called by muse, mutect2, varscan2
- METTL18 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV53682666; called by muse, mutect2, varscan2
- MGAT4C | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59833581, COSV59837675; called by muse, mutect2, varscan2
- MKRN2 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV50108540; called by muse, mutect2, varscan2
- MLANA | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV67367134; called by muse, mutect2, varscan2
- MLF1 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63035223; called by muse, mutect2, varscan2
- MOB1B | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV58675291; called by muse, mutect2, varscan2
- MROH1 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1028648067; called by muse, mutect2, varscan2
- MTFMT | c.1134G>C p.Q378H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.19); catalogued as COSV54979760; called by muse, mutect2, varscan2
- MYBBP1A | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54604216; called by muse, mutect2, varscan2
- MYH4 | c.1476C>G p.F492L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV55122114, COSV55122316, COSV55125975; called by muse, mutect2, varscan2
- MYH7B | c.5518G>A p.E1840K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs781585599, COSV52682988; called by muse, mutect2, varscan2
- MYO10 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV72563530; called by muse, mutect2
- MYO1D | c.2270G>T p.G757V | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59023240; called by muse, varscan2
- MYO5B | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV53230740; called by muse, mutect2, varscan2
- MYO7B | c.3163C>G p.Q1055E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV67351924; called by muse, mutect2, varscan2
- MYOM1 | c.2669A>T p.N890I | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as COSV55301062; called by muse, mutect2, varscan2
- MYOM3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.179); catalogued as rs768572077, COSV58400824; called by mutect2, varscan2
- NCKAP1 | c.2562C>A p.S854R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as COSV62943513; called by muse, mutect2, varscan2
- NCKIPSD | c.1812C>G p.F604L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV53663668; called by muse, mutect2, varscan2
- NCOA1 | c.2949C>G p.I983M | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56052790; called by muse, mutect2, varscan2
- NCOA1 | c.4129C>G p.L1377V | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56052812; called by muse, mutect2, varscan2
- NDUFAF7 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV50018861; called by muse, mutect2, varscan2
- NEB | c.9748G>C p.E3250Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV51459343; called by muse, mutect2, varscan2
- NEDD1 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV57146762; called by muse, mutect2, varscan2
- NEK4 | c.364T>G p.L122V | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51783282; called by muse, mutect2, varscan2
- NETO1 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV55015195; called by muse, mutect2, varscan2
- NF1 | c.4761del p.T1589Rfs*2 (on ENST00000358273 / NM_001042492.3; = p.T1568Rfs*2 on NM_000267.3) | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | catalogued as COSV62221210; called by mutect2, pindel, varscan2
- NFKBIB | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs371423502; called by muse, mutect2, varscan2
- NIPBL | c.4729G>A p.E1577K | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56942510, COSV56965620; called by muse, mutect2, varscan2
- NLRP7 | c.2918C>A p.P973H (on ENST00000340844 / NM_206828.3; = p.P1002H on NM_139176.3) | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.135); catalogued as COSV60178412; called by muse, mutect2, varscan2
- NOL9 | c.2042G>C p.R681T | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs537450957, COSV66626946; called by muse, mutect2, varscan2
- NOP2 | c.571G>C p.E191Q (on ENST00000322166 / NM_001258308.2; = p.E187Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1565590567, COSV59113596; called by muse, mutect2, varscan2
- NPAT | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 90/177 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as COSV53721703; called by muse, mutect2, varscan2
- NRCAM | c.1063G>C p.V355L (on ENST00000379028 / NM_001371124.1; = p.V349L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV61048713; called by muse, mutect2, varscan2
- NRP2 | c.2636T>C p.L879P (on ENST00000360409 / NM_201266.2; = p.L874P on NM_003872.3) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63377911; called by muse, mutect2, varscan2
- NTAQ1 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 125/172 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1404658016, COSV54876113; called by muse, mutect2, varscan2
- NUDT16 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as rs764633283, COSV63248930; called by muse, mutect2, varscan2
- NUP205 | c.3945A>C p.L1315F | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53665915; called by muse, mutect2, varscan2
- NXF1 | c.1606G>C p.V536L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV53676641; called by muse, mutect2, varscan2
- NXNL1 | c.300C>A p.F100L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV57325247, COSV57325473; called by muse, mutect2, varscan2
- OBSCN | c.20171C>G p.S6724C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV63453429; called by muse, varscan2
- ODF2 | c.1808T>A p.L603Q (on ENST00000434106 / NM_153433.2; = p.L579Q on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63548801, COSV63548926, COSV63549038; called by muse, mutect2, varscan2
- OGFOD1 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.079); catalogued as rs1208298112; called by muse, mutect2
- OR10J1 | c.416G>C p.R139T | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV71128619, COSV71129660; called by muse, mutect2
- OR13C3 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66166295; called by muse, mutect2, varscan2
- OR13C3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV66166299; called by muse, mutect2, varscan2
- OR1E2 | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV50266176; called by muse, mutect2, varscan2
- OR52B4 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68769488; called by muse, mutect2, varscan2
- OR5H1 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63403473; called by muse, mutect2, varscan2
- OR5K1 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 75/136 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.246); catalogued as COSV60305316; called by muse, mutect2, varscan2
- OR5M10 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV73242335; called by muse, mutect2, varscan2
- OR6N1 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58650410; called by muse, varscan2
- OSBP | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV55665647; called by muse, mutect2, varscan2
- PADI6 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV61885749; called by muse, mutect2, varscan2
- PARP10 | c.1012G>C p.G338R | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV57300133; called by muse, mutect2, varscan2
- PCDH7 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV62343412; called by muse, mutect2, varscan2
- PCDHB1 | c.1089G>C p.Q363H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV60633244; called by muse, mutect2, varscan2
- PCDHGA7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); catalogued as COSV54029982; called by muse, varscan2
- PCDHGA7 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.052); catalogued as COSV54029998; called by muse, varscan2
- PCOLCE2 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV56002105; called by muse, mutect2, varscan2
- PDE6C | c.1765G>T p.D589Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65117674; called by muse, mutect2, varscan2
- PDIA4 | c.1487C>G p.S496C (on ENST00000286091 / NM_001371244.1; = p.S495C on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV53726802; called by muse, mutect2
- PDZD2 | c.3488C>T p.S1163F | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV56872321; called by muse, mutect2, varscan2
- PEAK1 | c.4234G>C p.E1412Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV56942924; called by muse, mutect2, varscan2
- PFAS | c.143-2A>C p.X48_splice | Splice Site (SNP) | VAF 19/35 reads (54%) | catalogued as COSV58983203; called by muse, mutect2, varscan2
- PHF12 | c.864G>C p.Q288H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52022090; called by muse, mutect2, varscan2
- PHKB | c.3207G>C p.L1069F | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV54533848; called by muse, mutect2, varscan2
- PIGM | c.673C>G p.R225G | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63636068; called by muse, mutect2, varscan2
- PIGV | c.972G>C p.Q324H | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50304466; called by muse, mutect2, varscan2
- PIK3AP1 | c.1685G>T p.S562I | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV59530241; called by muse, mutect2, varscan2
- PIK3C2B | c.4217T>C p.F1406S | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65814260; called by muse, mutect2
- PIK3CD | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV63131782; called by muse, mutect2, varscan2
- PISD | c.945C>A p.F315L (on ENST00000439502 / NM_001326412.1; = p.F281L on NM_014338.3) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as COSV56718843; called by muse, mutect2, varscan2
- PKD1 | c.8788G>T p.D2930Y | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV51925420; called by muse, mutect2, varscan2
- PKD1 | c.8219G>A p.G2740E | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as COSV51925430; called by muse, mutect2, varscan2
- PLA2G4D | c.1539G>T p.R513S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs964165393, COSV51823769; called by muse, varscan2
- PLA2R1 | c.4108C>G p.Q1370E | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV51786470; called by muse, mutect2, varscan2
- PLB1 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV59835323; called by muse, mutect2
- PLCH2 | c.3440C>G p.S1147C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV53941861, COSV53949498; called by muse, mutect2, varscan2
- PLEKHA1 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64570353; called by muse, mutect2, varscan2
- PLEKHA3 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV52296570; called by muse, mutect2, varscan2
- PLEKHA4 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV54365459; called by muse, mutect2, varscan2
- PLEKHO1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs782745952, COSV50311357; called by muse, mutect2, varscan2
- PNMA8B | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV66537716; called by muse, mutect2, varscan2
- POLR1B | c.2850C>A p.F950L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54503687; called by muse, mutect2
- POP1 | c.682G>C p.V228L | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs755335901, COSV62894147; called by muse, mutect2, varscan2
- PPAT | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.446); catalogued as rs141469911; called by muse, mutect2, varscan2
- PPFIBP1 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.463); catalogued as COSV57298501; called by muse, mutect2, varscan2
- PPM1L | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV55570774; called by muse, mutect2, varscan2
- PPP1R12A | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54112531; called by muse, mutect2
- PPP4C | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV54223217; called by muse, mutect2, varscan2
- PRDM11 | c.1237G>C p.E413Q (on ENST00000530656 / NM_001359633.1; = p.E379Q on NM_001256695.1) | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); catalogued as COSV55439715, COSV99770684; called by muse, mutect2, varscan2
- PRDM5 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53367524; called by muse, mutect2, varscan2
- PRICKLE4 | c.743_744insTGT p.L248_A249insV (on ENST00000359201; = p.L288_A289insV on NM_013397.6) | In Frame Ins (INS) | VAF 32/76 reads (42%) | catalogued as rs72602856, COSV59253542; called by pindel, varscan2
- PRKAB2 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54214669; called by muse, mutect2
- PRKCI | c.1772C>G p.S591C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55522552; called by muse, mutect2, varscan2
- PRPF6 | c.1722G>C p.K574N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV53878516; called by muse, mutect2, varscan2
- PRPF8 | c.4145C>G p.S1382C | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59267733; called by muse, mutect2, varscan2
- PRR30 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV53208190; called by muse, mutect2, varscan2
- PRRC2C | c.283G>C p.E95Q (on ENST00000367742; = p.E93Q on NM_015172.4) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.653); catalogued as COSV58912915; called by muse, mutect2, varscan2
- PRRC2C | c.1330G>C p.D444H (on ENST00000367742; = p.D442H on NM_015172.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58911165; called by muse, mutect2, varscan2
- PRRT2 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV54884220, COSV54886367; called by muse, mutect2, varscan2
- PSIP1 | c.150-1G>T p.X50_splice | Splice Site (SNP) | VAF 16/16 reads (100%) | catalogued as COSV66255662; called by muse, mutect2, varscan2
- PSMC2 | c.264G>C p.Q88H | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53009061; called by muse, mutect2, varscan2
- PTBP1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV62461824; called by muse, mutect2, varscan2
- PTPN13 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.424); catalogued as COSV57417214; called by muse, mutect2, varscan2
- PTPN22 | c.109A>G p.K37E | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV63086573; called by muse, mutect2, varscan2
- PTPN9 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV60725981; called by muse, mutect2, varscan2
- PXK | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.455); catalogued as rs749273803, COSV57094494; called by muse, mutect2
- QRICH2 | c.4591C>G p.Q1531E | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV53157677; called by muse, mutect2, varscan2
- RAB12 | c.260G>C p.R87T | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV61399328; called by muse, mutect2, varscan2
- RAD50 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54753187, COSV99529083; called by muse, mutect2
- RALGAPB | c.3656G>T p.W1219L | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53438809, COSV53444108; called by muse, mutect2, varscan2
- RALGPS2 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV61339847; called by muse, mutect2, varscan2
- RALY | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV55783981; called by muse, mutect2, varscan2
- RANBP3 | c.798G>C p.L266F (on ENST00000340578 / NM_007322.3; = p.L261F on NM_003624.3) | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV50386302; called by muse, mutect2, varscan2
- RAPGEF4 | c.2478G>T p.W826C | Missense Mutation (SNP) | VAF 65/72 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51415296; called by muse, mutect2, varscan2
- RASSF8 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as COSV51455295; called by muse, mutect2, varscan2
- RBPJ | c.260T>C p.M87T | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.095); catalogued as COSV60756966; called by muse, mutect2, varscan2
- REC114 | c.570G>C p.Q190H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.41); catalogued as COSV100461482, COSV58524638; called by muse, mutect2, varscan2
- REV3L | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV62623353; called by muse, mutect2, varscan2
- RHBDF1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV51957945; called by muse, mutect2, varscan2
- RIC8B | c.669G>C p.E223D | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV62697085; called by muse, mutect2, varscan2
- RIMS2 | c.2542C>T p.H848Y (on ENST00000666250 / NM_001348490.2; = p.H656Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51723113; called by muse, mutect2, varscan2
- RIOK2 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV51615078; called by muse, mutect2, varscan2
- RIPK4 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs926446576; called by muse, mutect2
- RIPOR2 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as rs1304622009, COSV52429087; called by muse, mutect2, varscan2
- RNF103 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 22/151 reads (15%) | catalogued as COSV52896920; called by muse, mutect2, varscan2
- RNF139 | c.1524C>G p.I508M | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52682036; called by muse, mutect2, varscan2
- RNF148 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as rs886169027, COSV100411467, COSV57385384; called by muse, mutect2, varscan2
- RNF169 | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1179232542, COSV55135684; called by muse, mutect2, varscan2
- RNF31 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as rs1335199536, COSV53759615, COSV53760434; called by muse, mutect2, varscan2
- RNF31 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53761267; called by muse, mutect2, varscan2
- RPAP2 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV64861643; called by muse, mutect2, varscan2
- RPS6KA2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV55830132; called by muse, mutect2, varscan2
- RPS6KA6 | c.662A>G p.K221R | Missense Mutation (SNP) | VAF 56/67 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53126497; called by muse, mutect2, varscan2
- RRP1 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV68544765; called by muse, mutect2, varscan2
- RSL1D1 | c.1185G>C p.K395N | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV63078504; called by muse, mutect2
- RSPH10B2 | c.32A>T p.K11I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99786213; called by mutect2, varscan2
- RYR3 | c.5707C>T p.L1903F | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs1312654984, COSV66808040; called by muse, mutect2, varscan2
- RYR3 | c.6109G>A p.E2037K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66778282; called by muse, mutect2, varscan2
- RYR3 | c.10920G>A p.M3640I (on ENST00000389232; = p.M3641I on NM_001036.6) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.072); catalogued as COSV66808048; called by muse, mutect2
- S100A8 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 61/310 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV64197969, COSV64198263; called by muse, mutect2, varscan2
- SACS | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 67/70 reads (96%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs764585158, COSV66546685; called by muse, mutect2, varscan2
- SALL1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 111/168 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51764485, COSV51765123; called by muse, mutect2, varscan2
- SARNP | c.378-2A>G p.X126_splice | Splice Site (SNP) | VAF 78/339 reads (23%) | catalogued as COSV60244533; called by muse, mutect2, varscan2
- SCD5 | c.992G>C p.*331Sext*52 | Nonstop Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs1168314352; called by muse, mutect2, varscan2
- SCN1B | c.458A>T p.D153V | Missense Mutation (SNP) | VAF 102/196 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV52883481; called by muse, mutect2, varscan2
- SEL1L3 | c.3047C>G p.S1016C | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV53549438; called by muse, mutect2, varscan2
- SEMA6C | c.1041C>G p.F347L | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59005314, COSV59007749; called by muse, mutect2, varscan2
- SERINC5 | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV72597263; called by muse, mutect2, varscan2
- SERPINA3 | c.113A>C p.N38T | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV67587151; called by muse, mutect2, varscan2
- SERPINB2 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53075377, COSV99449605; called by muse, mutect2, varscan2
- SETD2 | c.6874C>G p.Q2292E | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57432238, COSV57447206; called by muse, mutect2, varscan2
- SF3B3 | c.3279G>T p.M1093I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56790998; called by muse, mutect2, varscan2
- SHOC1 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV59497406; called by muse, mutect2, varscan2
- SHROOM4 | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 28/29 reads (97%) | catalogued as COSV56792695; called by muse, mutect2, varscan2
- SIPA1L2 | c.4302G>C p.Q1434H | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs757351424, COSV53399712; called by muse, mutect2, varscan2
- SIPA1L2 | c.1058A>G p.K353R | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV53399727; called by muse, mutect2, varscan2
- SKIL | c.1728G>C p.Q576H | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as COSV52063012; called by muse, mutect2, varscan2
- SLA | c.460G>C p.E154Q (on ENST00000338087 / NM_001045556.3; = p.E194Q on NM_006748.4) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV55093708; called by muse, mutect2
- SLAIN2 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51910534; called by muse, mutect2, varscan2
- SLC10A2 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 71/78 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55361654; called by muse, mutect2, varscan2
- SLC10A6 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV56723445; called by muse, mutect2, varscan2
- SLC16A14 | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 56/67 reads (84%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV54621274; called by muse, mutect2, varscan2
- SLC22A8 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs766067506, COSV60325969; called by muse, mutect2, varscan2
- SLC25A19 | c.132+1G>A p.X44_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as COSV57468641; called by muse, mutect2, varscan2
- SLC25A31 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55421816; called by muse, mutect2, varscan2
- SLC25A40 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62021687; called by muse, mutect2, varscan2
- SLC32A1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54148362; called by muse, mutect2, varscan2
- SLC36A3 | c.1114T>C p.S372P | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.722); catalogued as COSV58858292; called by muse, mutect2, varscan2
- SLC4A10 | c.3187G>C p.D1063H (on ENST00000446997 / NM_001354461.2; = p.D1033H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV55769261; called by muse, mutect2
- SLC4A1AP | c.16C>A p.R6S | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.005); catalogued as COSV58137710; called by muse, mutect2, varscan2
- SLCO5A1 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 57/93 reads (61%) | catalogued as COSV52655145; called by muse, mutect2, varscan2
- SMARCA4 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60793423, COSV60808862; called by muse, mutect2, varscan2
- SMARCC2 | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57224879; called by muse, mutect2, varscan2
- SMC4 | c.3376G>C p.D1126H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV59087694; called by muse, mutect2, varscan2
- SMC5 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV63193571; called by muse, mutect2, varscan2
- SMG7 | c.2494G>C p.E832Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61629277; called by muse, mutect2, varscan2
- SNAPC4 | c.2568G>C p.K856N | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as COSV53737666; called by muse, mutect2, varscan2
- SNED1 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as rs1190481254, COSV60023284; called by muse, mutect2, varscan2
- SP7 | c.204T>A p.F68L | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.203); catalogued as COSV58192022; called by muse, mutect2, varscan2
- SPAG1 | c.2704G>C p.E902Q | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV52563388, COSV99308988; called by muse, mutect2
- SPEN | c.7561G>A p.D2521N | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.251); catalogued as COSV65365403, COSV65367383; called by muse, mutect2, varscan2
- SPINK5 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 31/36 reads (86%) | catalogued as COSV99806852; called by muse, mutect2, varscan2
- SPTA1 | c.3994C>T p.Q1332* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as COSV100934063; called by muse, mutect2, varscan2
- SPTAN1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV63989784; called by muse, mutect2, varscan2
- SPTBN2 | c.4928C>G p.T1643S | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.297); catalogued as COSV59461205; called by muse, mutect2, varscan2
- SPTBN4 | c.5812G>A p.V1938I | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV58958363; called by muse, mutect2, varscan2
- SREK1 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as COSV52335173; called by muse, mutect2
- SRRM4 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57426965; called by muse, mutect2, varscan2
- STAB2 | c.6326G>A p.S2109N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV66346894; called by muse, mutect2, varscan2
- STIL | c.3542C>T p.S1181F | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as COSV54553697; called by muse, mutect2, varscan2
- STK10 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1246675740, COSV51574427; called by muse, mutect2, varscan2
- STK38L | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV66523105; called by muse, mutect2, varscan2
- STX7 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.378); catalogued as rs777413406, COSV63399405; called by muse, mutect2, varscan2
- SUMF1 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1044335088; called by muse, mutect2
- SYNE1 | c.18930G>C p.Q6310H (on ENST00000367255 / NM_182961.4; = p.Q6239H on NM_033071.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV55098282; called by muse, mutect2, varscan2
- SYNE1 | c.18405G>C p.Q6135H (on ENST00000367255 / NM_182961.4; = p.Q6064H on NM_033071.3) | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); catalogued as COSV55098332; called by muse, mutect2
- TACSTD2 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64667355; called by muse, mutect2, varscan2
- TAF1L | c.4627G>C p.D1543H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV54268984; called by muse, mutect2, varscan2
- TAF2 | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV65421037; called by muse, mutect2, varscan2
- TAGAP | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV57851154, COSV57853125; called by muse, mutect2, varscan2
- TAS2R40 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV68818673; called by muse, mutect2, varscan2
- TBC1D31 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV54866489; called by muse, mutect2
- TBCK | c.694G>A p.E232K (on ENST00000273980 / NM_001163436.4; = p.E169K on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV56756037, COSV56762643; called by muse, mutect2, varscan2
- TBX4 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.954); catalogued as COSV53609716; called by muse, mutect2, varscan2
- TBXAS1 | c.1244C>G p.A415G | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as COSV54954085; called by muse, mutect2, varscan2
- TENM1 | c.2435-1G>C p.X812_splice | Splice Site (SNP) | VAF 38/41 reads (93%) | catalogued as COSV64442774; called by muse, mutect2, varscan2
- TENT5C | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.354); catalogued as COSV65617127; called by muse, mutect2, varscan2
- TEP1 | c.2580C>G p.D860E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52999913; called by muse, varscan2
- TEX14 | c.678G>C p.Q226H (on ENST00000240361 / NM_001201457.2; = p.Q220H on NM_031272.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.03); catalogued as COSV53626397; called by muse, mutect2, varscan2
- TGIF2 | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as COSV100872254, COSV100872284; called by muse, mutect2, varscan2
- TIMELESS | c.1903C>G p.Q635E | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.009); catalogued as rs765945106, COSV57515142; called by muse, mutect2, varscan2
- TLN1 | c.7105G>C p.E2369Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59211686; called by muse, mutect2, varscan2
- TMEM94 | c.2639C>G p.S880C | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58597631; called by muse, mutect2, varscan2
- TNFSF14 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV55591756; called by muse, mutect2, varscan2
- TNR | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54870333, COSV54912929; called by muse, mutect2, varscan2
- TNXB | c.9343G>A p.E3115K (on ENST00000647633; = p.E2868K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as rs764870462, COSV100926401; called by muse, mutect2
- TPTE | c.709C>G p.L237V (on ENST00000618007 / NM_199261.4; = p.L219V on NM_199259.4) | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752179158; called by muse, mutect2, varscan2
- TPTE2 | c.1168C>G p.L390V (on ENST00000400230 / NM_199254.2; = p.L313V on NM_130785.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55024270, COSV55028045; called by muse, mutect2, varscan2
- TRAK2 | c.1855A>G p.T619A | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1559437054, COSV60275001; called by muse, mutect2, varscan2
- TRAM1 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV51600495; called by muse, mutect2, varscan2
- TRAPPC10 | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.733); catalogued as COSV52381432; called by muse, mutect2, varscan2
- TRAPPC9 | c.3094G>A p.V1032M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs769543412, COSV66909501; called by muse, mutect2, varscan2
- TRAT1 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV55469879, COSV55470893; called by muse, mutect2, varscan2
- TRIM49 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100316043, COSV61670053; called by muse, mutect2, varscan2
- TTC21A | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57189427; called by muse, mutect2, varscan2
- TTC37 | c.3344C>G p.S1115C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763151101, COSV100706479; called by muse, mutect2, varscan2
- TTF2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.273); catalogued as COSV65633698; called by muse, mutect2, varscan2
- TTN | c.87706G>A p.V29236M (on ENST00000591111; = p.V21812M on NM_003319.4) | Missense Mutation (SNP) | VAF 53/97 reads (55%) | PolyPhen benign (0.428); catalogued as COSV60340999; called by muse, mutect2, varscan2
- TTN | c.70560G>C p.K23520N (on ENST00000591111; = p.K16096N on NM_003319.4) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | PolyPhen possibly damaging (0.626); catalogued as COSV60341067; called by muse, mutect2, varscan2
- TTN | c.35313G>C p.K11771N (on ENST00000591111; = p.K10844N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/130 reads (33%) | PolyPhen possibly damaging (0.714); catalogued as COSV60195358, COSV60341103; called by muse, mutect2, varscan2
- TUB | c.1051C>T p.Q351* (on ENST00000299506 / NM_177972.3; = p.Q406* on NM_003320.4) | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100210004; called by muse, mutect2, varscan2
- TUBB4A | c.761C>G p.A254G | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV51158381, COSV51165854, COSV51169526; called by muse, mutect2, varscan2
- TULP1 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1394261825, COSV57693865; called by muse, mutect2, varscan2
- TXNDC11 | c.2929G>C p.E977Q (on ENST00000356957 / NM_001303447.2; = p.E950Q on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV51603101; called by muse, mutect2, varscan2
- UACA | c.2088G>C p.Q696H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV59859863; called by muse, mutect2, varscan2
- UBA6 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs868294417, COSV59180958; called by muse, mutect2, varscan2
- UBASH3A | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.141); catalogued as COSV52316097; called by muse, mutect2, varscan2
- UBE2V2 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV72879267; called by muse, mutect2, varscan2
- UBR4 | c.12099G>T p.K4033N | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.261); catalogued as COSV64399142; called by muse, mutect2, varscan2
- UBR5 | c.5204C>G p.S1735C | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs1427487889, COSV55300000; called by muse, mutect2
- UBTF | c.780G>T p.M260I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV57188378; called by muse, mutect2
- UEVLD | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57877032; called by muse, mutect2
- UGP2 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61427925; called by muse, mutect2, varscan2
- UNC5A | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52844445; called by muse, mutect2, varscan2
- USE1 | c.275C>G p.P92R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.957); catalogued as COSV55728824; called by muse, mutect2, varscan2
- USP16 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV57627878; called by muse, mutect2, varscan2
- USP34 | c.9037C>G p.Q3013E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV68406406; called by muse, mutect2, varscan2
- UTP20 | c.7741G>C p.D2581H | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.174); catalogued as COSV55385209; called by muse, mutect2, varscan2
- VPS13B | c.9505G>C p.D3169H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV62156646; called by muse, mutect2, varscan2
- VPS13B | c.10573G>A p.E3525K | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV62145343, COSV62156651; called by muse, mutect2, varscan2
- VPS13D | c.6424G>C p.E2142Q | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV50682114; called by muse, mutect2, varscan2
- VPS33A | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV57356269, COSV57357108; called by muse, mutect2, varscan2
- VPS51 | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54209439; called by muse, mutect2, varscan2
- WASHC3 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53531252, COSV53533366; called by muse, mutect2, varscan2
- WDR19 | c.3955G>C p.E1319Q | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV56469971; called by muse, mutect2, varscan2
- WDR62 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54339362, COSV99544346; called by muse, mutect2, varscan2
- WSB2 | c.624C>G p.D208E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59575038; called by muse, mutect2, varscan2
- XYLT2 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV50021923; called by muse, mutect2, varscan2
- ZBTB40 | c.3580G>C p.E1194Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.609); catalogued as COSV65146396; called by muse, mutect2, varscan2
- ZBTB46 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99828825; called by muse, mutect2
- ZFC3H1 | c.4612C>G p.L1538V | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV66435790; called by muse, mutect2
- ZFP69 | c.1040G>A p.R347K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV65529184, COSV65529577; called by muse, mutect2, varscan2
- ZFPM2 | c.2874C>G p.N958K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV65875843; called by muse, mutect2, varscan2
- ZHX1 | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV52879025; called by muse, mutect2, varscan2
- ZNF223 | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71572176, COSV71572186; called by muse, mutect2, varscan2
- ZNF223 | c.1238C>G p.S413* | Nonsense Mutation (SNP) | VAF 15/156 reads (10%) | catalogued as COSV71571838; called by muse, mutect2
- ZNF276 | c.1170-1G>C p.X390_splice (on ENST00000443381 / NM_001113525.2; = p.X315_splice on NM_152287.4) | Splice Site (SNP) | VAF 31/144 reads (22%) | catalogued as COSV57073143; called by muse, mutect2, varscan2
- ZNF318 | c.2636C>G p.S879C | Missense Mutation (SNP) | VAF 75/80 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100546437, COSV58937491; called by muse, mutect2, varscan2
- ZNF45 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs747087833, COSV54194727; called by muse, mutect2, varscan2
- ZNF491 | c.811C>G p.H271D | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV60058856; called by muse, mutect2, varscan2
- ZNF513 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV52010394; called by muse, mutect2
- ZNF543 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58629370; called by muse, mutect2, varscan2
- ZNF544 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV54138414, COSV99517140; called by muse, mutect2, varscan2
- ZNF544 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV54138423; called by muse, mutect2, varscan2
- ZNF550 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV57307477; called by muse, mutect2, varscan2
- ZNF574 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as COSV55906810; called by muse, mutect2, varscan2
- ZNF665 | c.1441G>A p.D481N (on ENST00000600412; = p.D546N on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 182/271 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV67217506; called by muse, mutect2, varscan2
- ZNF7 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV57385363; called by muse, mutect2, varscan2
- ZNF761 | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 82/308 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV61889467; called by muse, mutect2
- ZNF787 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54420343; called by muse, mutect2, varscan2
- ZNF800 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56179838; called by muse, mutect2, varscan2
- ZNF816 | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 88/320 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54412482, COSV99554372; called by muse, mutect2, varscan2
- ZNF878 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72155965; called by muse, mutect2, varscan2
- ZZEF1 | c.2207C>T p.T736I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as rs1312354847, COSV67560216; called by muse, mutect2
- ABCA9 | c.1955C>G p.S652* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- ABCB8 | c.1339G>C p.E447Q (on ENST00000297504 / NM_001282291.2; = p.E430Q on NM_007188.5) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); called by muse, varscan2
- ACACA | c.6546C>G p.I2182M | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP6 | c.462_476del p.R155_L159del | In Frame Del (DEL) | VAF 30/66 reads (45%) | called by mutect2, pindel, varscan2
- AREL1 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- ASPG | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- ATMIN | c.1568C>G p.S523* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- BBOF1 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- BEND3 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- BRD1 | c.1424_1441del p.R475_W480del | In Frame Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- C8orf34 | c.570_571del p.S191* | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by pindel, varscan2
- CDAN1 | c.1458-14_1474del p.X486_splice | Splice Site (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- CDH4 | c.1301_1319del p.S434Tfs*9 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, pindel
- CDK12 | c.283del p.E95Rfs*29 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- CDK5 | c.841_852del p.L281_P284del | In Frame Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- CDRT1 | c.1434-8_1443del p.X478_splice | Splice Site (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- CMTM4 | c.705G>C p.*235Yext*15 | Nonstop Mutation (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- DCAF6 | c.2407G>C p.D803H (on ENST00000312263 / NM_001349778.1; = p.D823H on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2
- DMKN | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.03); called by muse, mutect2
- DNAH3 | c.3938A>T p.K1313M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2
- EFCAB5 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- FHOD1 | c.212G>C p.C71S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GOSR1 | c.427_431del p.K144Yfs*2 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel*, varscan2*
- HELB | c.455C>G p.S152* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- HHLA2 | c.611C>G p.S204* | Nonsense Mutation (SNP) | VAF 52/84 reads (62%) | called by muse, mutect2, varscan2
- HUWE1 | c.10136C>T p.S3379F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IPO13 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | called by muse, mutect2, varscan2
- IQUB | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- KBTBD7 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 87/98 reads (89%) | called by muse, mutect2, varscan2
- KIAA1522 | c.2573C>G p.S858* (on ENST00000373480 / NM_001198972.2; = p.S917* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- LHFPL5 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- LSG1 | c.1415C>G p.S472* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- MDH1B | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- MEOX2 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- MEPCE | c.940del p.Q314Nfs*124 | Frame Shift Del (DEL) | VAF 84/172 reads (49%) | called by mutect2, pindel, varscan2
- MID2 | c.486T>A p.C162* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- MMEL1 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- MMP17 | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MPV17L2 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- NCKAP5 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- NMT2 | c.1268C>G p.S423* | Nonsense Mutation (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- NUTM1 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- OR8G2P | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PCSK6 | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- PIK3C2B | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- PKDREJ | c.1072_1117del p.G358Sfs*19 | Frame Shift Del (DEL) | VAF 39/113 reads (35%) | called by mutect2, pindel
- PLA2G1B | c.446G>T p.*149Lext*20 | Nonstop Mutation (SNP) | VAF 67/264 reads (25%) | called by muse, mutect2, varscan2
- PTEN | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RABL2A | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- RASGRP3 | c.1379T>A p.V460D (on ENST00000402538 / NM_001349975.2; = p.V459D on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.013); called by muse, mutect2
- RFPL4B | c.642_652del p.L215Pfs*4 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- RPS6KA5 | c.1127C>G p.S376C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SEC24B | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- SERPING1 | c.612_641del p.C205_T214del | In Frame Del (DEL) | VAF 22/139 reads (16%) | called by mutect2, pindel
- SF3B1 | c.3734G>C p.R1245T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- SLC9C2 | c.1269C>G p.Y423* | Nonsense Mutation (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- SLFN11 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2
- SPTBN1 | c.5968G>T p.E1990* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- SPTBN5 | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- STK36 | c.1052C>G p.S351* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- SYNE2 | c.3619C>T p.Q1207* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- TANC1 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- TEAD3 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- TICAM1 | c.1384_1401del p.C462_H467del | In Frame Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- TRBV6-1 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- UNC13D | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- YWHAZ | c.616_634del p.L206Kfs*5 | Frame Shift Del (DEL) | VAF 34/174 reads (20%) | called by mutect2, pindel
- ABCA4 | c.5937A>C p.T1979= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1384890737, COSV64677918; called by muse, mutect2, varscan2
- ABHD17B | c.111G>A p.L37= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as rs995994587, COSV61009126; called by muse, mutect2
- ACSS3 | c.1803C>G p.L601= | Silent (SNP) | VAF 39/215 reads (18%) | catalogued as COSV54101080; called by muse, mutect2, varscan2
- ACTN4 | c.1206G>A p.L402= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV53150667; called by muse, mutect2, varscan2
- ADAM22 | c.507C>G p.L169= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV55984165; called by muse, mutect2, varscan2
- ADCY5 | c.750G>A p.V250= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs759766616, COSV71901636; called by muse, mutect2, varscan2
- ADGRB3 | c.2763C>T p.I921= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV53245603; called by muse, mutect2, varscan2
- AMIGO2 | c.153C>A p.I51= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV56974219, COSV56975561; called by muse, mutect2, varscan2
- AMOT | c.2049G>A p.Q683= (on ENST00000371959 / NM_001113490.1; = p.Q274= on NM_133265.3) | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV59068109; called by muse, mutect2, varscan2
- AMPD2 | c.609G>C p.L203= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV56650540; called by muse, varscan2
- AMY2A | c.517A>C p.R173= | Silent (SNP) | VAF 42/188 reads (22%) | catalogued as COSV101340646; called by mutect2, varscan2
- AP1S1 | c.324G>A p.E108= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV50802378; called by muse, mutect2, varscan2
- APH1A | c.213C>T p.L71= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV52530601; called by muse, mutect2, varscan2
- ARMC5 | c.48C>T p.L16= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV51655029, COSV51657963, COSV51659455; called by muse, mutect2, varscan2
- ATMIN | c.2280G>A p.L760= | Silent (SNP) | VAF 46/191 reads (24%) | catalogued as COSV55147617; called by muse, varscan2
- ATP10A | c.2154G>A p.L718= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV63524005; called by muse, mutect2
- BABAM2 | c.402G>A p.E134= | Silent (SNP) | VAF 96/144 reads (67%) | catalogued as COSV59632800; called by muse, mutect2, varscan2
- BCORL1 | c.2787G>A p.Q929= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV54406645; called by muse, mutect2, varscan2
- BPIFB4 | c.1443C>A p.I481= | Silent (SNP) | VAF 32/310 reads (10%) | catalogued as COSV64952321; called by muse, mutect2
- C17orf80 | c.270G>T p.V90= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV52145386, COSV52146838, COSV52148743; called by muse, mutect2, varscan2
- C20orf144 | c.273G>T p.P91= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs754114109, COSV55778600; called by muse, varscan2
- CC2D1A | c.2769G>C p.L923= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV54309837; called by muse, mutect2, varscan2
- CCDC88A | c.2736G>T p.V912= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV55069811; called by muse, mutect2, varscan2
- CCR8 | c.834G>A p.L278= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV58337974; called by muse, mutect2, varscan2
- CELA3B | c.27C>T p.L9= | Silent (SNP) | VAF 68/276 reads (25%) | catalogued as COSV61405600; called by muse, varscan2
- CLDN16 | c.195T>C p.D65= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV53229295; called by muse, mutect2, varscan2
- CLIP1 | c.2298C>G p.L766= (on ENST00000620786 / NM_001247997.1; = p.L755= on NM_002956.2) | Silent (SNP) | VAF 53/165 reads (32%) | catalogued as COSV56808452; called by muse, mutect2, varscan2
- CNIH3 | c.60C>T p.L20= | Silent (SNP) | VAF 39/230 reads (17%) | catalogued as rs373044474; called by muse, mutect2, varscan2
- CNTNAP4 | c.2646A>G p.E882= | Silent (SNP) | VAF 48/198 reads (24%) | catalogued as COSV56699727; called by muse, mutect2, varscan2
- COL16A1 | c.2814C>T p.L938= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1239085030, COSV54713644, COSV99595284; called by muse, mutect2, varscan2
- COL9A1 | c.1573A>C p.R525= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV57892972; called by muse, mutect2, varscan2
- CPA6 | c.171G>A p.K57= | Silent (SNP) | VAF 40/56 reads (71%) | catalogued as COSV52742400; called by muse, mutect2, varscan2
- CRIM1 | c.180C>T p.C60= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1367244208, COSV54872480; called by muse, mutect2, varscan2
- CRIP1 | c.87G>A p.L29= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV57636173; called by muse, mutect2, varscan2
- CRYZ | c.138T>A p.G46= | Silent (SNP) | VAF 71/112 reads (63%) | catalogued as COSV61718595; called by muse, mutect2, varscan2
- CSF3R | c.1974C>A p.L658= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV58971837; called by muse, mutect2, varscan2
- CYFIP1 | c.3012C>T p.I1004= | Silent (SNP) | VAF 46/72 reads (64%) | catalogued as rs760077367, COSV57415872; called by muse, varscan2
- CYP4F8 | c.204T>G p.T68= | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2
- CYP8B1 | c.393G>C p.L131= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV60227631; called by muse, mutect2, varscan2
- DDX23 | c.1815C>T p.F605= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV56400852; called by muse, mutect2
- DHX29 | c.1149G>C p.L383= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV52422204; called by muse, mutect2, varscan2
- DIO2 | c.159C>T p.R53= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV70446464; called by muse, mutect2, varscan2
- DNAH10 | c.4329C>A p.L1443= (on ENST00000409039; = p.L1382= on NM_207437.3) | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV69001317; called by muse, mutect2, varscan2
- DOCK3 | c.5886C>T p.V1962= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV56549244; called by muse, mutect2, varscan2
- DOCK9 | c.2322C>T p.I774= (on ENST00000376460 / NM_001366676.2; = p.I775= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV59643132; called by muse, mutect2, varscan2
- DRD2 | c.606C>T p.F202= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV60762778; called by muse, mutect2, varscan2
- DYNC1LI2 | c.258A>T p.L86= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV50756492; called by muse, mutect2, varscan2
- DYSF | c.2385C>T p.I795= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV50576215; called by muse, mutect2, varscan2
- EPAS1 | c.447C>G p.L149= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV55390344; called by muse, mutect2, varscan2
- EPHA10 | c.315G>A p.L105= | Silent (SNP) | VAF 79/144 reads (55%) | catalogued as COSV60405622; called by muse, mutect2, varscan2
- ERAP2 | c.2650C>T p.L884= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV101163897, COSV65941372; called by muse, mutect2, varscan2
- ERCC3 | c.2097A>G p.E699= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV53429901; called by muse, mutect2, varscan2
- FAAP24 | c.561G>C p.L187= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as COSV54274921, COSV54286537; called by muse, mutect2, varscan2
- FAM229B | c.21C>A p.T7= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs781890060, COSV64087589; called by muse, mutect2, varscan2
- FCGBP | c.9234C>T p.F3078= | Silent (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- FCGBP | c.5631C>T p.F1877= | Silent (SNP) | VAF 81/379 reads (21%) | called by muse, mutect2, varscan2
- FCGBP | c.1101C>T p.I367= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs912361800; called by muse, mutect2, varscan2
- FLG | c.5910T>A p.S1970= | Silent (SNP) | VAF 239/874 reads (27%) | catalogued as COSV64248935; called by muse, mutect2
- GDPGP1 | c.603C>T p.F201= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs779887210, COSV61576138; called by muse, mutect2, varscan2
- GLO1 | c.51C>T p.L17= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as COSV64905671; called by muse, mutect2, varscan2
- GOLGA4 | c.5193G>A p.Q1731= | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as COSV62713760; called by muse, mutect2, varscan2
- GPA33 | c.684C>G p.V228= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV63302304; called by muse, mutect2, varscan2
- GSC2 | c.573G>A p.A191= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV50082692; called by muse, mutect2, varscan2
- GTSF1L | c.66C>T p.F22= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as COSV65932871; called by muse, mutect2, varscan2
- HSD17B7 | c.339G>A p.V113= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2
- IHO1 | c.744G>A p.L248= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV56510882; called by muse, mutect2, varscan2
- ING4 | c.531C>G p.T177= (on ENST00000396807 / NM_001127582.2; = p.T176= on NM_016162.4) | Silent (SNP) | VAF 29/151 reads (19%) | catalogued as COSV57525333; called by muse, mutect2, varscan2
- INPP5D | c.1392C>T p.I464= (on ENST00000445964 / NM_001017915.3; = p.I463= on NM_005541.5) | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV64040303; called by muse, mutect2, varscan2
- INTS7 | c.2355G>A p.L785= | Silent (SNP) | VAF 46/74 reads (62%) | catalogued as COSV65345478; called by muse, mutect2, varscan2
- IPO7 | c.1458G>A p.V486= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV63352888; called by muse, mutect2, varscan2
- ITPR1 | c.7596G>T p.L2532= (on ENST00000354582; = p.L2477= on NM_002222.7) | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV57003390; called by muse, mutect2, varscan2
- ITSN1 | c.1353G>T p.R451= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV66085955; called by muse, mutect2, varscan2
- KIRREL2 | c.1947C>A p.V649= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs758152893, COSV52880030; called by muse, mutect2, varscan2
- KLK5 | c.540T>C p.S180= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV60451565; called by muse, mutect2, varscan2
- KRT84 | c.1119C>T p.N373= | Silent (SNP) | VAF 43/199 reads (22%) | catalogued as rs747600631, COSV57773662; called by muse, mutect2, varscan2
- LIG1 | c.1065C>G p.L355= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as rs763944587, COSV54395979; called by muse, mutect2, varscan2
- LIN28A | c.567C>G p.T189= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV54263167; called by muse, mutect2, varscan2
- LMAN1L | c.453C>T p.I151= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV59003701; called by muse, mutect2
- LONP2 | c.1839C>T p.I613= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV53526152; called by muse, mutect2, varscan2
- LRFN4 | c.405C>T p.I135= | Silent (SNP) | VAF 64/81 reads (79%) | catalogued as rs1341069537, COSV58920542, COSV58923384; called by muse, mutect2, varscan2
- LRP2 | c.8736G>A p.K2912= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV55573659; called by muse, mutect2, varscan2
- LRRIQ1 | c.3606G>A p.K1202= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV67828737, COSV67828808; called by muse, mutect2, varscan2
- LRRTM1 | c.1371C>A p.L457= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV54446563; called by muse, mutect2, varscan2
- LY9 | c.63G>A p.Q21= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as COSV54437040; called by muse, mutect2, varscan2
- MICAL1 | c.2868G>A p.L956= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV57806287, COSV57807048; called by muse, mutect2, varscan2
- MLH1 | c.57C>T p.I19= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs762647509, COSV51616921, COSV51623813; called by muse, mutect2, varscan2
- MMP25 | c.465C>G p.L155= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV60681285; called by muse, mutect2, varscan2
- MOB1B | c.159C>T p.L53= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV58675298; called by muse, mutect2, varscan2
- MRPS16 | c.195C>G p.L65= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as COSV60286801, COSV60286893; called by muse, mutect2, varscan2
- MUC16 | c.8355G>C p.V2785= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV101201770, COSV67492736; called by muse, mutect2, varscan2
- MXRA5 | c.6783G>A p.L2261= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV54222275; called by muse, mutect2, varscan2
- MYO15A | c.5598G>C p.L1866= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV52765843; called by muse, mutect2, varscan2
- MYOC | c.540G>A p.L180= | Silent (SNP) | VAF 91/392 reads (23%) | catalogued as rs760063838, COSV50678774; called by muse, mutect2, varscan2
- NALCN | c.70C>T p.L24= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV51964495; called by muse, mutect2, varscan2
- NCKAP5L | c.300G>A p.L100= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs768057977, COSV60133417, COSV60134609; called by muse, mutect2, varscan2
- NECAP2 | c.36C>T p.V12= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV59188757, COSV59188773; called by muse, mutect2, varscan2
- NELFB | c.1611C>T p.F537= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as rs1440044130, COSV58026488; called by muse, mutect2, varscan2
- NKTR | c.4383C>T p.Y1461= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV51775255; called by mutect2, varscan2
- NOMO3 | c.1173C>T p.I391= | Silent (SNP) | VAF 44/178 reads (25%) | catalogued as COSV53770606; called by muse, mutect2, varscan2
- NOTCH1 | c.2568C>G p.V856= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV53093125; called by muse, mutect2, varscan2
- NOX4 | c.942C>T p.V314= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV54464415; called by muse, mutect2, varscan2
- NRXN2 | c.798C>T p.S266= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs751041121, COSV55461375; called by muse, mutect2, varscan2
- OR2A14 | c.666C>T p.A222= | Silent (SNP) | VAF 119/253 reads (47%) | catalogued as rs773698940, COSV101376494, COSV68718477, COSV68718683; called by muse, mutect2, varscan2
- OR2Z1 | c.99C>T p.V33= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV60693304; called by muse, mutect2, varscan2
- OXGR1 | c.477C>T p.I159= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- OXSR1 | c.1404C>G p.L468= | Silent (SNP) | VAF 52/207 reads (25%) | catalogued as COSV61260530; called by muse, mutect2, varscan2
- PCDH17 | c.618G>A p.Q206= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1393716645, COSV64979023; called by muse, mutect2, varscan2
- PCDH7 | c.1425C>T p.D475= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV62343425; called by muse, mutect2, varscan2
- PCDHB2 | c.2319C>T p.I773= | Silent (SNP) | VAF 58/71 reads (82%) | catalogued as COSV50575112; called by muse, mutect2, varscan2
- PCDHB5 | c.1647G>A p.L549= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs149096993; called by muse, mutect2, varscan2
- PDE11A | c.1386G>A p.E462= | Silent (SNP) | VAF 75/76 reads (99%) | catalogued as COSV53708252; called by muse, mutect2, varscan2
- PIGQ | c.1648C>T p.L550= (on ENST00000026218 / NM_148920.3; = p.I570= on NM_004204.5) | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as COSV50321335; called by muse, mutect2, varscan2
- PIK3R5 | c.324C>T p.T108= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV52658627; called by muse, mutect2, varscan2
- PLCB3 | c.1293C>G p.S431= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV54192310; called by muse, mutect2, varscan2
- PNOC | c.252C>A p.L84= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as rs907274496, COSV100108398, COSV57284584; called by muse, mutect2, varscan2
- PNPLA6 | c.2061G>A p.L687= (on ENST00000414982 / NM_001166111.2; = p.L639= on NM_006702.5) | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV55384834; called by muse, mutect2, varscan2
- POLR1A | c.573C>A p.L191= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV55699590; called by muse, mutect2, varscan2
- POP5 | c.159C>T p.F53= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs1421315855, COSV58048167; called by muse, varscan2
- PPP1R2 | c.297C>T p.I99= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV60498583; called by muse, mutect2, varscan2
- PRCC | c.1224C>T p.I408= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV54858571; called by muse, mutect2, varscan2
- PRKAB2 | c.231G>A p.R77= | Silent (SNP) | VAF 101/277 reads (36%) | catalogued as COSV54214680; called by muse, mutect2
- PRKCH | c.1440G>C p.L480= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as COSV60652366; called by muse, mutect2, varscan2
- PRKD2 | c.1644C>T p.V548= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV52189650; called by muse, mutect2, varscan2
- PRPF8 | c.4269C>T p.F1423= | Silent (SNP) | VAF 109/120 reads (91%) | catalogued as COSV59267726; called by muse, mutect2, varscan2
- PRRC1 | c.558C>T p.T186= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs777921896, COSV56991980; called by muse, mutect2, varscan2
75 further variants in this file (0 protein-altering or splice-affecting, 59 silent, 16 other) are not listed here.
